Somatic mutation profile of tumor specimen TCGA-DX-A8BT-01A (aliquot TCGA-DX-A8BT-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 63.5 years (23,204 days).
Specimen TCGA-DX-A8BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d587e82f-4230-4761-89a8-0f8a636da984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BT-10A (Blood Derived Normal), aliquot TCGA-DX-A8BT-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7ea9890-94de-4ba8-ab33-953f252d7bce

The open-access MAF lists 90 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, Nonsense Mutation 6, Splice Site 2, Splice Region 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV101330044, COSV70042618; called by muse, mutect2, varscan2
- ACAD8 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1164263704, COSV99844331; called by muse, mutect2
- ACRBP | c.527T>G p.V176G | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV99976131; called by muse, mutect2, varscan2
- ADAMTS20 | c.4000G>T p.E1334* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV101166259, COSV67131877; called by muse, mutect2, varscan2
- AGGF1 | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100461858; called by muse, mutect2, varscan2
- ASTN2 | c.1582C>A p.P528T (on ENST00000313400 / NM_001365069.1; = p.P477T on NM_014010.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100527486; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs531117418, COSV100022536; called by muse, mutect2, varscan2
- ATP8A2 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99681996; called by muse, mutect2, varscan2
- ATRX | c.4317+1G>A p.X1439_splice | Splice Site (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100970789; called by muse, mutect2, varscan2
- BOD1 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV99603454; called by muse, mutect2, varscan2
- BRD7 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101164925; called by muse, mutect2, varscan2
- CAMK2B | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99323054; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CDH9 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as COSV50251398, COSV50263956; called by muse, mutect2
- CYP3A4 | c.1577C>A p.S526* (on ENST00000336411; = p.S495* on NM_017460.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100315660; called by muse, mutect2, varscan2
- DCC | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101472999; called by muse, mutect2, varscan2
- DOCK6 | c.1336T>G p.F446V | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV99370977; called by muse, mutect2, varscan2
- DOCK8 | c.4135A>T p.M1379L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101209935; called by muse, mutect2, varscan2
- DRD3 | c.892G>T p.V298F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as COSV55680491; called by muse, mutect2, varscan2
- ERCC6L | c.3697G>T p.D1233Y | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559116; called by muse, mutect2, varscan2
- FBXO40 | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV100573171; called by muse, mutect2, varscan2
- GLIS1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV100390043; called by muse, varscan2
- GMFG | c.341C>G p.T114R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.354); catalogued as rs772969335, COSV99453359; called by muse, mutect2, varscan2
- HDC | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV99984027, COSV99984379; called by muse, mutect2, varscan2
- HTR2C | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99349369; called by muse, mutect2, varscan2
- IL20RA | c.1289C>A p.T430K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100359969; called by muse, mutect2, varscan2
- KRT6A | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs1376577077, COSV100416992; called by muse, mutect2, varscan2
- LCA5L | c.333A>T p.E111D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV99903621; called by muse, mutect2
- MED12L | c.5502A>G p.P1834= | Splice Region (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99853187, COSV99854398; called by muse, mutect2, varscan2
- MROH2B | c.3763T>A p.W1255R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV101270678; called by muse, mutect2
- MUC17 | c.4934G>T p.S1645I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV100073211, COSV60283431, COSV60283750; called by muse, mutect2, varscan2
- NME9 | c.226A>T p.K76* (on ENST00000333911 / NM_001349024.2; = p.K54* on NM_178130.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV58623071; called by muse, mutect2, varscan2
- NOA1 | c.1712T>C p.L571S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV99950530; called by muse, mutect2, varscan2
- OR13G1 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.778); catalogued as COSV100687263; called by muse, mutect2
- OR1L1 | c.943A>T p.N315Y (on ENST00000373686; = p.N265Y on NM_001005236.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100542169; called by muse, mutect2, varscan2
- OR2J3 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as rs751049860, COSV65849350; called by muse, mutect2, varscan2
- PCDHAC2 | c.1781T>G p.V594G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99147906; called by muse, mutect2, varscan2
- PCDHB13 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99507278; called by muse, mutect2, varscan2
- PELO | c.497A>T p.N166I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV99251327; called by muse, mutect2, varscan2
- PHKA1 | c.3644T>G p.L1215R | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100263200; called by muse, mutect2, varscan2
- POF1B | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99426703; called by muse, mutect2, varscan2
- PRAG1 | c.2528C>A p.A843E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100422190; called by muse, mutect2, varscan2
- PRAG1 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100422191; called by muse, mutect2, varscan2
- PZP | c.3661G>A p.A1221T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); catalogued as rs577575931, COSV99737862; called by muse, mutect2, varscan2
- RNF138 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV55235970; called by muse, mutect2
- SCN2A | c.971-1G>T p.X324_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99331719; called by muse, mutect2, varscan2
- SCN9A | c.4180C>A p.L1394I (on ENST00000303354; = p.L1383I on NM_002977.3) | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100312823, COSV100314262; called by muse, mutect2, varscan2
- SLCO5A1 | c.1366C>A p.P456T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99480050; called by muse, mutect2, varscan2
- SNRPE | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100919287; called by muse, mutect2, varscan2
- SPEF2 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100607420; called by muse, mutect2, varscan2
- SPHKAP | c.1733A>G p.E578G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs370073181, COSV60871423; called by muse, mutect2, varscan2
- SRPK2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100623975; called by muse, mutect2, varscan2
- SYNE1 | c.3957C>A p.S1319R (on ENST00000367255 / NM_182961.4; = p.S1326R on NM_033071.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs1272204034, COSV99564514; called by muse, mutect2, varscan2
- TENM4 | c.2320A>T p.K774* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99574735; called by muse, mutect2, varscan2
- THAP7 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99301786; called by muse, mutect2, varscan2
- TM6SF2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99895067; called by muse, mutect2, varscan2
- TUBA4A | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs775821469, COSV99944781; called by muse, mutect2, varscan2
- USH2A | c.9355C>T p.R3119C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs576236830, COSV56335521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR46 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101005630; called by muse, mutect2, varscan2
- WHAMM | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as rs1173130833, COSV99724913; called by muse, mutect2
- WNK3 | c.4358C>T p.S1453F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1312487747, COSV100671411; called by muse, mutect2, varscan2
- ZNF343 | c.271A>T p.M91L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99601423; called by muse, mutect2, varscan2
- ZNF85 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.244); catalogued as COSV100059792, COSV56021156; called by muse, mutect2, varscan2
- DNAJC13 | c.5561G>A p.G1854D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, varscan2
- TMEM117 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- ADAM22 | c.1356T>A p.I452= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99716955; called by muse, mutect2, varscan2
- ADAM29 | c.1776A>G p.G592= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV63663196; called by muse, mutect2, varscan2
- ASPHD2 | c.1101G>T p.P367= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- BMP2K | c.2508C>T p.L836= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs773371419, COSV99785106; called by muse, mutect2, varscan2
- CACNA1B | c.1290C>T p.H430= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs768863269, COSV53157201; called by muse, varscan2
- CECR2 | c.2628G>A p.V876= (on ENST00000342247 / NM_001290047.2; = p.V693= on NM_001290046.1) | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV99377975; called by muse, mutect2, varscan2
- CPAMD8 | c.1959C>A p.I653= (on ENST00000651564; = p.I606= on NM_015692.5) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99359397; called by muse, mutect2, varscan2
- FAM186B | c.2160C>G p.L720= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99219020; called by muse, mutect2, varscan2
- GLP1R | c.600C>T p.A200= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100952598; called by muse, mutect2, varscan2
- GPR37 | c.1734G>T p.V578= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100390809; called by muse, mutect2, varscan2
- HIVEP3 | c.7062T>C p.S2354= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99912630; called by mutect2, varscan2
- IFITM1 | c.162C>T p.F54= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100068236; called by muse, mutect2, varscan2
- IPO13 | c.571C>A p.R191= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100961204; called by muse, mutect2, varscan2
- LPAR3 | c.465C>T p.I155= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs565409119, COSV65452543; called by muse, mutect2, varscan2
- MEP1A | c.2235G>A p.R745= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV57917859; called by muse, mutect2
- NOP53 | c.21C>T p.G7= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV54407685; called by muse, mutect2, varscan2
- NPHP4 | c.4050C>A p.I1350= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs770113955, COSV100976908; called by muse, mutect2, varscan2
- PAGE3 | c.285G>T p.L95= | Silent (SNP) | VAF 74/300 reads (25%) | catalogued as COSV100891992; called by muse, mutect2, varscan2
- PAQR9 | c.699C>T p.T233= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100503701; called by muse, mutect2, varscan2
- PIK3CB | c.84C>G p.G28= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100005663; called by muse, mutect2, varscan2
- PMFBP1 | c.1383G>T p.L461= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99400900; called by muse, mutect2, varscan2
- SLC25A48 | c.276C>T p.C92= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs368023667, COSV99192019; called by muse, mutect2, varscan2
- SRPK2 | c.99A>T p.P33= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100623979, COSV61962480; called by muse, mutect2, varscan2
- SSPOP | n.6018C>A | RNA (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100022528; called by muse, mutect2, varscan2
